Somatic mutation profile of tumor specimen TCGA-EM-A2CJ-01A (aliquot TCGA-EM-A2CJ-01A-11D-A17V-08) from TCGA case TCGA-EM-A2CJ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 49.7 years (18,168 days).
Specimen TCGA-EM-A2CJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3040478-d136-4d2d-96dc-e75260bfa91e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2CJ-10A (Blood Derived Normal), aliquot TCGA-EM-A2CJ-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c270e489-9dc3-49f1-80d4-50e63ef9c9cf

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Splice Site 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.622G>T p.D208Y (on ENST00000372530 / NM_001198934.2; = p.D165Y on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs754616362, COSV55094996; called by muse, mutect2, varscan2
- CCDC27 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs762056417, COSV53904285; called by mutect2, varscan2
- ERGIC2 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as COSV64111831, COSV64113654; called by muse, mutect2
- FRRS1 | c.1274C>A p.T425N | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54925049; called by muse, mutect2, varscan2
- IFI16 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as rs1163649622, COSV55541202; called by muse, mutect2, varscan2
- MIA3 | c.4028A>C p.K1343T | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV60519109; called by muse, mutect2
- RPL4 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs1186027247, COSV57183855; called by muse, mutect2, varscan2
- TCF3 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs535762587, COSV53652561; called by muse, mutect2, varscan2
- TRPM5 | c.2356G>C p.G786R | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV50215016; called by muse, mutect2, varscan2
- COPG1 | c.1545-21_1553del p.X515_splice | Splice Site (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel
- TTC16 | c.1181del p.L394Rfs*86 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | called by mutect2, varscan2
- MUC16 | c.32628A>T p.G10876= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as COSV67500972; called by muse, mutect2, varscan2
